Somatic mutation profile of tumor specimen TCGA-G3-A25U-01A (aliquot TCGA-G3-A25U-01A-11D-A16V-10) from TCGA case TCGA-G3-A25U, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.5 years (23,207 days).
Specimen TCGA-G3-A25U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c90cbb2-0f6e-4d74-9844-5832776075a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25U-10A (Blood Derived Normal), aliquot TCGA-G3-A25U-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec082dbb-f285-4563-a524-4be5bd4747d9

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Splice Site 3, Nonsense Mutation 3, In Frame Del 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 37/48 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AC013489.1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as rs367738496; called by muse, mutect2, varscan2
- AMER1 | c.2576A>T p.Y859F | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57663573; called by muse, mutect2, varscan2
- APAF1 | c.3128A>G p.H1043R (on ENST00000551964 / NM_181861.2; = p.H989R on NM_001160.3) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV59665907; called by muse, mutect2, varscan2
- ARHGAP33 | c.1017T>G p.I339M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV50133536; called by muse, mutect2, varscan2
- ARHGEF39 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV58397528; called by muse, mutect2, varscan2
- CD1E | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV63771913; called by muse, mutect2, varscan2
- CEP70 | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV53876708; called by muse, mutect2, varscan2
- COL15A1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as COSV66647197; called by muse, mutect2, varscan2
- COL22A1 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194439406, COSV57347010; called by muse, mutect2, varscan2
- DHODH | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs955893236, COSV54662975; called by mutect2, varscan2
- DNAI4 | c.2113-1G>A p.X705_splice | Splice Site (SNP) | VAF 82/175 reads (47%) | catalogued as COSV64030299; called by muse, mutect2, varscan2
- ERBB4 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53504234; called by muse, mutect2, varscan2
- HIPK3 | c.1305A>T p.K435N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57563828; called by muse, mutect2, varscan2
- HIPK3 | c.1307A>C p.E436A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV57563838; called by muse, mutect2, varscan2
- HYDIN | c.14884A>G p.T4962A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.337); catalogued as COSV66640345; called by mutect2, varscan2
- IGHV3-11 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.298); catalogued as rs547199875; called by muse, mutect2
- IL16 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV57265892; called by muse, mutect2, varscan2
- KANSL1 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV52270981; called by muse, mutect2, varscan2
- LONRF3 | c.2020G>A p.V674I (on ENST00000371628 / NM_001031855.3; = p.V633I on NM_024778.5) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59154571, COSV59154632; called by muse, mutect2, varscan2
- LRRC10 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.199); catalogued as rs201257055, COSV64060229, COSV64060517; called by muse, mutect2, varscan2
- MAGI2 | c.3713C>A p.P1238H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV62679032; called by muse, mutect2, varscan2
- MIEN1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54075855; called by muse, mutect2
- MUC16 | c.39640C>G p.P13214A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.932); catalogued as COSV66694545; called by muse, mutect2
- MYO18A | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62869992; called by muse, mutect2, varscan2
- NBEA | c.2750A>G p.Y917C | Missense Mutation (SNP) | VAF 104/111 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs776613118, COSV59801350; called by muse, mutect2, varscan2
- PIK3CA | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55953569; called by muse, mutect2, varscan2
- PPP2CB | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV55329022; called by muse, mutect2, varscan2
- PPP2R5C | c.1506C>A p.D502E | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV58273818; called by muse, mutect2, varscan2
- PTPN2 | c.860A>C p.K287T | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV58997940; called by mutect2, varscan2
- PTPRG | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs916309143, COSV55650711; called by muse, mutect2, varscan2
- SCGB2A2 | c.244-1G>C p.X82_splice | Splice Site (SNP) | VAF 16/33 reads (48%) | catalogued as COSV57174757; called by muse, mutect2, varscan2
- SDHA | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53770975; called by muse, mutect2, varscan2
- SHROOM3 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs879246777, COSV56034155; called by muse, mutect2, varscan2
- SNX6 | c.473T>G p.V158G (on ENST00000652385; = p.V30G on NM_021249.5) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV61919323; called by muse, mutect2, varscan2
- SREBF1 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748730943, COSV55395473; called by muse, mutect2, varscan2
- STARD5 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57155426; called by muse, mutect2, varscan2
- SUCNR1 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV62912539; called by muse, mutect2, varscan2
- TFDP2 | c.955G>T p.G319* (on ENST00000489671 / NM_001178139.2; = p.G259* on NM_006286.5) | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV57709204; called by muse, mutect2, varscan2
- TFDP2 | c.954G>T p.M318I (on ENST00000489671 / NM_001178139.2; = p.M258I on NM_006286.5) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV57709212; called by muse, mutect2, varscan2
- TULP3 | c.1214A>T p.Q405L | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68118293; called by muse, mutect2, varscan2
- VPS51 | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54208545; called by muse, mutect2, varscan2
- WDR90 | c.4247C>T p.T1416M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs576866547, COSV53466355; called by muse, mutect2, varscan2
- ZFP36 | c.768C>A p.C256* (on ENST00000594442; = p.C250* on NM_003407.5) | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV50529506; called by muse, mutect2, varscan2
- CYP3A5 | c.1388_1390del p.S463del | In Frame Del (DEL) | VAF 60/158 reads (38%) | called by mutect2, pindel, varscan2
- RB1 | c.1196dup p.N399Kfs*7 | Frame Shift Ins (INS) | VAF 242/359 reads (67%) | called by mutect2, pindel, varscan2
- TEX11 | c.631_633del p.L211del (on ENST00000344304; = p.L196del on NM_031276.3) | In Frame Del (DEL) | VAF 60/157 reads (38%) | called by mutect2, pindel, varscan2
- TNPO1 | c.2143+2dup p.X715_splice | Splice Site (INS) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- AHNAK | c.11478G>T p.V3826= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV57221316; called by muse, mutect2, varscan2
- BAP1 | c.2118C>A p.I706= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs201122466; called by mutect2, varscan2
- CAP2 | c.255G>A p.Q85= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV57734367; called by muse, mutect2, varscan2
- GABRB2 | c.174C>T p.P58= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs1385011173, COSV50904636, COSV99196298; called by muse, mutect2, varscan2
- HK1 | c.1945C>T p.L649= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV53861662; called by muse, mutect2, varscan2
- MAP1A | c.2794T>C p.L932= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55808418; called by muse, mutect2, varscan2
- NISCH | c.1329A>G p.T443= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV61901138; called by muse, mutect2
- NPHP1 | c.108T>C p.A36= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs770032884, COSV57209942; called by muse, mutect2, varscan2
- OR14K1 | c.210T>C p.C70= | Silent (SNP) | VAF 35/37 reads (95%) | catalogued as COSV99315415; called by muse, mutect2, varscan2
- PROKR1 | c.1047C>A p.T349= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1484543815, COSV58138348; called by muse, mutect2, varscan2
- SATB1 | c.549A>G p.Q183= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs61733671, COSV100113571, COSV58671131; called by muse, mutect2, varscan2
- STYXL2 | c.2103C>A p.S701= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54807473; called by mutect2, varscan2
- TMED4 | c.360G>A p.R120= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV56942196; called by muse, mutect2, varscan2
- TNMD | c.811C>A p.R271= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV65976837, COSV65977435; called by muse, mutect2, varscan2
- ZNF804B | c.819A>G p.T273= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as rs1332337743, COSV60839188; called by muse, mutect2, varscan2
- MIR888 | n.64T>G | RNA (SNP) | VAF 29/55 reads (53%) | called by muse, varscan2
